Somatic mutation profile of tumor specimen HCM-BROD-0339-C43-06A (aliquot HCM-BROD-0339-C43-06A-01D-A79C-36) from HCMI case HCM-BROD-0339-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 36.3 years (13,251 days).
Specimen HCM-BROD-0339-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1db0a37d-3632-4250-8c3e-c35aa820b80a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0339-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0339-C43-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e0577f1-7636-482a-9842-10ddb62ad1a8

The open-access MAF lists 383 somatic variants for this specimen: 254 protein-altering or splice-affecting, 119 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 230, Silent 119, Nonsense Mutation 16, Intron 4, 3'UTR 3, Frame Shift Ins 2, Splice Region 2, Splice Site 2, Frame Shift Del 1, RNA 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 41/314 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- AC092143.1 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 75/585 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV104396250; called by muse, mutect2, varscan2
- ADCY8 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53895961, COSV99654440; called by muse, mutect2
- ADGRG3 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 41/315 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368211978; called by muse, mutect2, varscan2
- ADORA2A | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 71/502 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.254); catalogued as rs1287369177, COSV58379373; called by muse, mutect2, varscan2
- ADORA2A | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 71/530 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.091); catalogued as COSV58377927; called by muse, mutect2, varscan2
- ANKRD30B | c.3539C>T p.P1180L | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV100271401; called by muse, mutect2, varscan2
- ANO4 | c.383C>T p.S128F (on ENST00000392977 / NM_001286615.2; = p.S93F on NM_178826.4) | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs199936621, COSV100152378; called by muse, mutect2, varscan2
- ARMC4 | c.3055G>A p.D1019N | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.139); catalogued as COSV59456466, COSV59461306; called by muse, mutect2, varscan2
- ARMC4 | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as COSV100536616; called by muse, mutect2
- ARVCF | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs762406853; called by muse, mutect2, varscan2
- B3GALT1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 44/449 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as rs866876110, COSV59909329; called by muse, mutect2, varscan2
- BICD1 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 65/475 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV55688702; called by muse, mutect2, varscan2
- BRINP3 | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 122/518 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV66524819; called by muse, mutect2, varscan2
- BSN | c.6749G>A p.R2250Q | Missense Mutation (SNP) | VAF 52/470 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1299983273; called by muse, varscan2
- C11orf86 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 47/490 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV100456973; called by muse, mutect2, varscan2
- C1orf56 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 92/589 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1305196726; called by muse, mutect2, varscan2
- CACNA1F | c.5006C>T p.P1669L | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV100544681; called by muse, mutect2, varscan2
- CACNA1H | c.2935G>A p.V979I | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs759796507; called by muse, mutect2, varscan2
- CALCR | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.458); catalogued as COSV64006005; called by muse, mutect2, varscan2
- CDH6 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54074005; called by muse, mutect2, varscan2
- CGNL1 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748559258, COSV55572722; called by muse, mutect2, varscan2
- CHD6 | c.4157C>T p.S1386L | Missense Mutation (SNP) | VAF 53/250 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs764458413; called by muse, mutect2, varscan2
- COL1A1 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751890158, COSV56807243; called by muse, mutect2, varscan2
- COL22A1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753523862, COSV57333838; called by muse, mutect2, varscan2
- COL28A1 | c.2189G>A p.G730D | Missense Mutation (SNP) | VAF 42/373 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as rs373271322; called by muse, mutect2, varscan2
- COL2A1 | c.3023G>A p.G1008D | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765795867, CD063499, COSV100477239; called by muse, mutect2, varscan2
- COL4A3 | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs368342782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A4 | c.3707G>A p.G1236E | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61632820; called by muse, mutect2, varscan2
- COL5A3 | c.3023C>A p.S1008Y | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs781508162; called by muse, mutect2, varscan2
- CPA2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.68); catalogued as rs201088138; called by muse, mutect2, varscan2
- CSMD3 | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.815); catalogued as rs566426423, COSV52109016, COSV52145907; called by muse, mutect2, varscan2
- CYP26C1 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 74/719 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs1176947666; called by muse, mutect2
- CYP26C1 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 76/720 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs762204088; called by muse, mutect2
- DDN | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 71/842 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.273); catalogued as rs753561904; called by muse, mutect2
- DDX4 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 49/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61754856; called by muse, mutect2, varscan2
- DMBT1 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 58/618 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs571730382, COSV57563473; called by muse, mutect2
- DNAH3 | c.5209G>A p.E1737K | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as rs755641783; called by muse, mutect2, varscan2
- DNAH7 | c.2855G>A p.G952E | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs775319314; called by muse, mutect2
- DYNC2H1 | c.12550C>T p.R4184C | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767920377, COSV62086491; called by muse, mutect2, varscan2
- EMB | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV57480619; called by muse, mutect2, varscan2
- ENPP6 | c.1009C>G p.P337A | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as COSV99699179; called by muse, mutect2, varscan2
- EVC2 | c.1992G>T p.K664N | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100185399; called by muse, mutect2
- FAM135B | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 57/479 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV52719715, COSV99417311; called by muse, mutect2, varscan2
- FAN1 | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 59/449 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146600264; called by muse, mutect2, varscan2
- FSHR | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs765583608; called by muse, mutect2, varscan2
- GALNT2 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775177578, COSV64194107; called by muse, mutect2, varscan2
- GLI2 | c.3266G>A p.G1089D (on ENST00000361492 / NM_001374353.1; = p.G1106D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/678 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs777267988, CM055283, COSV58050697; called by muse, mutect2
- GLYAT | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1413090557; called by muse, mutect2, varscan2
- GMPS | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55811566; called by muse, mutect2, varscan2
- GOLGA6L6 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.316); catalogued as rs749175278; called by muse, mutect2, varscan2
- GPR78 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 123/791 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs1317676429; called by muse, mutect2, varscan2
- GRB7 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58446672; called by muse, mutect2, varscan2
- GRM7 | c.2452C>T p.L818F | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as COSV63136401; called by muse, varscan2
- HCN1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100299579; called by muse, mutect2, varscan2
- HTR2A | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 72/481 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs778682687, COSV101096643, COSV99059994; called by muse, mutect2, varscan2
- IFNA6 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1181102432, COSV66506695; called by muse, mutect2, varscan2
- KAT6B | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 52/439 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.549); catalogued as rs756038238, COSV54742537; called by muse, mutect2, varscan2
- KATNB1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as rs782579971; called by muse, mutect2, varscan2
- KIAA0232 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 42/344 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV56923345; called by muse, mutect2, varscan2
- KLF14 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 48/734 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1342956484; called by muse, mutect2
- KMT2C | c.6016C>T p.H2006Y | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV51427466; called by muse, mutect2, varscan2
- LOXL3 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs1290840534, COSV99239844; called by muse, mutect2
- LRATD1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 60/734 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99707314; called by muse, mutect2
- LRIF1 | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100870950; called by mutect2, varscan2
- MAGEC2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV56001522; called by muse, mutect2, varscan2
- MAP7D2 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101107525; called by muse, mutect2, varscan2
- MET | c.2873G>A p.R958K | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV59268688; called by muse, mutect2
- METTL2A | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 55/443 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs988722853; called by muse, mutect2, varscan2
- MGA | c.7396C>T p.R2466* (on ENST00000219905 / NM_001164273.1; = p.R2257* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 20/156 reads (13%) | catalogued as COSV54950944; called by muse, mutect2, varscan2
- MROH2A | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 37/382 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752653076; called by muse, mutect2
- MUC16 | c.41624G>A p.R13875K | Missense Mutation (SNP) | VAF 47/427 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV66696243; called by muse, mutect2, varscan2
- MUC16 | c.24874G>A p.A8292T | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.01); catalogued as rs778216388, COSV67443869; called by muse, mutect2, varscan2
- MUC16 | c.18389C>T p.S6130F | Missense Mutation (SNP) | VAF 40/489 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as rs780590119; called by muse, mutect2
- MYH10 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV52609854; called by muse, mutect2, varscan2
- NCOR1 | c.6848G>A p.G2283E | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV51981993, COSV99252735; called by muse, mutect2, varscan2
- NIF3L1 | c.807A>G p.I269M (on ENST00000409020 / NM_001369444.1; = p.I242M on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/418 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.844); catalogued as COSV62899968; called by muse, mutect2
- NLRP12 | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747186204; called by muse, mutect2, varscan2
- NLRP3 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 86/400 reads (22%) | catalogued as COSV60231908; called by muse, mutect2, varscan2
- NLRP5 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as rs1361699751, COSV66766154; called by muse, mutect2, varscan2
- NRK | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 90/329 reads (27%) | catalogued as COSV54600407; called by muse, mutect2, varscan2
- OR51E1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs751394816, COSV67809975; called by muse, mutect2
- OTOF | c.1834C>T p.L612F | Missense Mutation (SNP) | VAF 47/364 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV55518978; called by muse, mutect2, varscan2
- P2RX4 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 26/278 reads (9%) | catalogued as rs767702661; called by muse, mutect2
- PAXIP1 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 51/468 reads (11%) | catalogued as COSV68188023; called by muse, mutect2, varscan2
- PCDHGA1 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs866306738, COSV65296140; called by muse, mutect2, varscan2
- PCLO | c.7237C>T p.P2413S | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.165); catalogued as rs1310852371; called by muse, mutect2
- PDE4DIP | c.6110A>G p.Q2037R | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as rs1559410614; called by muse, mutect2, varscan2
- PEAK1 | c.4823C>T p.P1608L | Missense Mutation (SNP) | VAF 62/495 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56942992; called by muse, mutect2, varscan2
- PKHD1L1 | c.3836G>A p.G1279E | Missense Mutation (SNP) | VAF 55/412 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as rs867986792, COSV65741514; called by muse, mutect2, varscan2
- PLEKHH1 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 53/404 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs775323773, COSV61284006, COSV61288809; called by muse, mutect2, varscan2
- PLEKHH3 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 47/406 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs1227815984; called by muse, mutect2, varscan2
- PLIN2 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.811); catalogued as rs1182340269; called by muse, mutect2, varscan2
- POM121L12 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 82/712 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs766446464, COSV68693059, COSV68694334; called by muse, varscan2
- PREX2 | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1213028913, COSV55766250; called by muse, mutect2, varscan2
- PSG8 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs142736244; called by muse, mutect2, varscan2
- PTPRD | c.2878G>A p.D960N | Missense Mutation (SNP) | VAF 66/387 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs1381492310, COSV61989344; called by muse, mutect2, varscan2
- PXDN | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 57/517 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53234044; called by muse, mutect2, varscan2
- RAD54L | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1449828957; called by muse, mutect2, varscan2
- RASIP1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 91/681 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs746117962; called by muse, mutect2, varscan2
- RELN | c.6470C>T p.P2157L | Missense Mutation (SNP) | VAF 45/389 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1412766990; called by muse, mutect2, varscan2
- RNASE12 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 35/377 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100250459, COSV60087590; called by muse, mutect2
- RSAD2 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV101149912; called by muse, mutect2, varscan2
- SAMD7 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs772594842, COSV100157064, COSV59420723; called by muse, varscan2
- SAMHD1 | c.346A>C p.K116Q | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.659); catalogued as COSV99484010; called by muse, mutect2, varscan2
- SCN1A | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 54/511 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.585); catalogued as rs755323236; called by muse, mutect2, varscan2
- SDC3 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 75/512 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1466152141; called by muse, mutect2, varscan2
- SELP | c.1396G>C p.G466R | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs753794052; called by muse, varscan2
- SEPTIN3 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 49/581 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1162204321; called by muse, mutect2
- SERHL2 | c.614-1G>A p.X205_splice | Splice Site (SNP) | VAF 29/276 reads (11%) | catalogued as COSV59669815; called by muse, mutect2, varscan2
- SERHL2 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763405033; called by muse, mutect2, varscan2
- SLCO2A1 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1181672885, COSV100188632; called by muse, mutect2, varscan2
- TACC1 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 68/427 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs201280385; called by muse, mutect2, varscan2
- TBX18 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 48/338 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV63737494, COSV63738579; called by muse, mutect2, varscan2
- THSD7B | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55654466; called by muse, mutect2
- TIAM2 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 39/336 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as rs201514936; called by muse, mutect2, varscan2
- TICRR | c.4649C>T p.S1550F | Missense Mutation (SNP) | VAF 45/363 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as COSV51543903; called by muse, mutect2, varscan2
- TLR2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52605815; called by muse, mutect2, varscan2
- TRBV19 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1459424317; called by muse, mutect2, varscan2
- TRIM33 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.675); catalogued as COSV100635188; called by muse, mutect2, varscan2
- TSPYL5 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 91/868 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1472423885; called by muse, mutect2, varscan2
- TTN | c.82030G>A p.G27344R (on ENST00000591111; = p.G19920R on NM_003319.4) | Missense Mutation (SNP) | VAF 60/441 reads (14%) | PolyPhen probably damaging (1); catalogued as rs748946057, COSV100605094, COSV59901297; called by muse, mutect2, varscan2
- TTN | c.71129G>A p.W23710* (on ENST00000591111; = p.W16286* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 44/385 reads (11%) | catalogued as COSV60258811; called by muse, mutect2, varscan2
- TTN | c.42916G>A p.E14306K (on ENST00000591111; = p.E6882K on NM_003319.4) | Missense Mutation (SNP) | VAF 19/293 reads (6%) | PolyPhen benign (0.053); catalogued as rs1240010379, COSV59922255; called by muse, mutect2
- TTN | c.28447G>A p.D9483N (on ENST00000591111; = p.D8556N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/273 reads (11%) | PolyPhen benign (0.118); catalogued as COSV60244303; called by muse, mutect2, varscan2
- ZAN | c.7346G>A p.R2449K | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs1287281798; called by muse, mutect2
- ZNF106 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs1345782972; called by muse, mutect2, varscan2
- ZNF318 | c.4741C>T p.P1581S | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as rs57667731; called by muse, mutect2, varscan2
- ZNF461 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 48/343 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs780052934; called by muse, mutect2, varscan2
- ZNF680 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 23/272 reads (8%) | catalogued as COSV59015187; called by muse, mutect2, varscan2
- ZP1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 56/517 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV53925007; called by muse, mutect2, varscan2
- ABCA10 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ABCF2 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ACBD4 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ADRA2A | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 24/648 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); called by muse, mutect2
- AFDN | c.3052A>T p.M1018L | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- AMY2B | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 45/292 reads (15%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.5654C>T p.P1885L | Missense Mutation (SNP) | VAF 67/428 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ARVCF | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 61/472 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- BDKRB1 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 77/553 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- BRD4 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BTNL3 | c.344G>A p.W115* | Nonsense Mutation (SNP) | VAF 53/404 reads (13%) | called by muse, mutect2, varscan2
- C1QTNF9B | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 124/826 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- CALCOCO1 | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 63/328 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CALCRL | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- CBLIF | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CDHR2 | c.3022C>T p.L1008F | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKL4 | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- CFAP20DC | c.1867del p.I623Sfs*15 | Frame Shift Del (DEL) | VAF 51/380 reads (13%) | called by mutect2, pindel, varscan2
- CLCNKA | c.1639G>T p.V547L | Missense Mutation (SNP) | VAF 49/324 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CLSTN3 | c.1697_1698+2delinsGAA p.X566_splice | Splice Site (DEL) | VAF 35/207 reads (17%) | called by pindel, varscan2*
- CNKSR1 | c.1669C>T p.P557S (on ENST00000374253 / NM_001297647.2; = p.P550S on NM_006314.3) | Missense Mutation (SNP) | VAF 74/557 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- CNKSR1 | c.1670C>T p.P557L (on ENST00000374253 / NM_001297647.2; = p.P550L on NM_006314.3) | Missense Mutation (SNP) | VAF 71/556 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- COCH | c.1462G>A p.D488N (on ENST00000216361 / NM_001347720.1; = p.D423N on NM_004086.3) | Missense Mutation (SNP) | VAF 48/347 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COL28A1 | c.1769T>C p.I590T | Missense Mutation (SNP) | VAF 50/428 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- COL4A5 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CTAGE4 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 42/704 reads (6%) | called by muse, mutect2
- DMRT3 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH6 | c.10294C>T p.H3432Y | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- DSCAML1 | c.5032G>A p.E1678K (on ENST00000321322; = p.E1618K on NM_020693.4) | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DUOX1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- DUOX1 | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- EEF1A2 | c.267C>G p.I89M | Missense Mutation (SNP) | VAF 54/453 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- EFR3B | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 30/520 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EMCN | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- ENKUR | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPB41L1 | c.2209G>A p.G737R | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ERBB3 | c.3258_3275del p.M1087_L1092del | In Frame Del (DEL) | VAF 48/380 reads (13%) | called by mutect2, pindel, varscan2
- ERICH6B | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 150/606 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC4 | c.2564G>A p.G855D | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- F8 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAIM2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- FBRS | c.301C>T p.Q101* (on ENST00000287468; = p.Q621* on NM_001105079.3) | Nonsense Mutation (SNP) | VAF 45/336 reads (13%) | called by muse, mutect2, varscan2
- FHL5 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- FIGNL1 | c.1631C>G p.A544G | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNIP1 | c.2601dup p.E868Rfs*11 | Frame Shift Ins (INS) | VAF 33/275 reads (12%) | called by mutect2, pindel, varscan2
- GALNT5 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GULP1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HR | c.3205C>T p.L1069F | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTATSF1 | c.800T>G p.I267S | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- IGKV2-30 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- IGKV2-30 | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.282); called by muse, mutect2
- JMJD7-PLA2G4B | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 47/437 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNK13 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 61/350 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KNL1 | c.2780C>G p.T927S (on ENST00000346991 / NM_170589.5; = p.T901S on NM_144508.5) | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRK2 | c.5395G>T p.D1799Y | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MBD5 | c.4469G>A p.R1490K | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MEFV | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MGAM2 | c.5692C>T p.P1898S | Missense Mutation (SNP) | VAF 56/579 reads (10%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2
- MORN1 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYH9 | c.3904G>A p.D1302N | Missense Mutation (SNP) | VAF 54/428 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MYH9 | c.2945T>G p.I982S | Missense Mutation (SNP) | VAF 54/488 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO15B | c.8468C>G p.P2823R | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- MYO1H | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 44/359 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO9A | c.6967G>A p.E2323K | Missense Mutation (SNP) | VAF 50/440 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- MYPN | c.204C>G p.S68R | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NANOGP8 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 49/471 reads (10%) | called by muse, mutect2, varscan2
- NFXL1 | c.1910T>A p.I637N | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- NLRC5 | c.2625G>A p.V875= | Splice Region (SNP) | VAF 23/249 reads (9%) | called by muse, mutect2
- NUDT13 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NUTM2B | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- OR10Z1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 123/504 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR4C16 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR4D6 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PAX4 | c.145-7G>A | Splice Region (SNP) | VAF 54/474 reads (11%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1409T>C p.L470P | Missense Mutation (SNP) | VAF 104/870 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLCG2 | c.1937G>A p.W646* | Nonsense Mutation (SNP) | VAF 33/277 reads (12%) | called by muse, mutect2, varscan2
- POF1B | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- POU3F1 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 82/657 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PRR12 | c.1378T>G p.F460V (on ENST00000615927; = p.F1281V on NM_020719.3) | Missense Mutation (SNP) | VAF 81/493 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PRUNE2 | c.8242C>T p.L2748F | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PTPN13 | c.2336A>C p.H779P | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBP3 | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 48/479 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- RERE | c.2927C>T p.S976F | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- RGS7 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGS9 | c.1682T>G p.L561R | Missense Mutation (SNP) | VAF 81/544 reads (15%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHAG | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF31 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 58/512 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, varscan2
- RYR1 | c.8560G>A p.G2854S | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SEC14L1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SFXN2 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 52/396 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SH3PXD2A | c.2432C>T p.P811L (on ENST00000369774 / NM_001365079.1; = p.P783L on NM_014631.2) | Missense Mutation (SNP) | VAF 59/636 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- SH3RF3 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 67/554 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SMAD1 | c.197C>A p.T66N | Missense Mutation (SNP) | VAF 47/415 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SMARCA5 | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SPOCD1 | c.1321A>G p.S441G | Missense Mutation (SNP) | VAF 108/466 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.084); called by muse, mutect2
- SPRYD3 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 63/474 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D15 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TEX43 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- THOC1 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TKTL2 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 60/423 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM201 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 74/478 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- TNFRSF8 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 71/457 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TPH1 | c.1223T>A p.I408N | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TRABD2A | c.821C>T p.P274L (on ENST00000409520 / NM_001277053.2; = p.P225L on NM_001080824.3) | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TRAPPC9 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.248); called by muse, mutect2
- TRIM43B | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- TRIM47 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 50/403 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRIM77 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TSPAN10 | c.457_458insT p.P153Lfs*31 (on ENST00000574882 / NM_001290212.1; = p.P115Lfs*31 on NM_031945.4) | Frame Shift Ins (INS) | VAF 64/535 reads (12%) | called by mutect2, pindel, varscan2
- TTLL6 | c.2552C>T p.P851L (on ENST00000393382 / NM_001130918.3; = p.P544L on NM_173623.3) | Missense Mutation (SNP) | VAF 48/373 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); called by muse, varscan2
- TTLL9 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TXN2 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 48/434 reads (11%) | called by muse, varscan2
- TYW3 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 31/301 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDPCP | c.1642C>T p.L548F | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- WHAMM | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- WNT6 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 88/953 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.744); called by muse, mutect2
- ZC3HAV1 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZFHX3 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 83/508 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ZNF180 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF287 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 47/336 reads (14%) | called by muse, mutect2, varscan2
- ZNF544 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 59/372 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZSWIM5 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 80/609 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCF2 | c.390T>C p.A130= | Silent (SNP) | VAF 36/264 reads (14%) | called by muse, varscan2
- ACSS3 | c.534C>T p.I178= | Silent (SNP) | VAF 49/326 reads (15%) | catalogued as rs764965164; called by muse, mutect2, varscan2
- ADA2 | c.654C>T p.I218= | Silent (SNP) | VAF 50/388 reads (13%) | called by muse, varscan2
- ADGRL3 | c.822G>T p.V274= (on ENST00000506720 / NM_001322402.2; = p.V206= on NM_015236.6) | Silent (SNP) | VAF 42/392 reads (11%) | called by muse, mutect2
- AL160272.2 | c.108C>T p.L36= | Silent (SNP) | VAF 43/286 reads (15%) | called by muse, mutect2, varscan2
- ANGPT1 | c.678A>G p.Q226= | Silent (SNP) | VAF 44/384 reads (11%) | called by muse, mutect2, varscan2
- ANKRD13B | c.1194G>A p.A398= | Silent (SNP) | VAF 48/393 reads (12%) | catalogued as rs776199636, COSV61472472; called by muse, mutect2, varscan2
- ANO4 | c.384C>T p.S128= (on ENST00000392977 / NM_001286615.2; = p.S93= on NM_178826.4) | Silent (SNP) | VAF 54/408 reads (13%) | called by muse, mutect2, varscan2
- AP4B1 | c.438G>A p.K146= | Silent (SNP) | VAF 31/234 reads (13%) | called by muse, mutect2, varscan2
- APBB1IP | c.312C>T p.F104= | Silent (SNP) | VAF 49/461 reads (11%) | catalogued as rs894488051; called by muse, mutect2, varscan2
- APOBR | c.2319G>A p.L773= (on ENST00000431282; = p.L782= on NM_018690.4) | Silent (SNP) | VAF 63/440 reads (14%) | called by muse, mutect2, varscan2
- ARAP1 | c.1764G>T p.R588= (on ENST00000393609 / NM_001040118.2; = p.R343= on NM_015242.4) | Silent (SNP) | VAF 69/530 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.576G>A p.Q192= (on ENST00000383472 / NM_001366230.1; = p.Q33= on NM_001010000.3) | Silent (SNP) | VAF 59/378 reads (16%) | catalogued as COSV51643706; called by muse, mutect2, varscan2
- ARSD | c.1606C>T p.L536= | Silent (SNP) | VAF 57/269 reads (21%) | called by muse, mutect2, varscan2
- ASPHD1 | c.522C>T p.G174= | Silent (SNP) | VAF 54/512 reads (11%) | called by muse, mutect2, varscan2
- C20orf194 | c.634C>T p.L212= | Silent (SNP) | VAF 32/269 reads (12%) | catalogued as rs763557076; called by muse, mutect2, varscan2
- CASP5 | c.223C>T p.L75= | Silent (SNP) | VAF 28/258 reads (11%) | catalogued as rs1249901937; called by muse, varscan2
- CDHR2 | c.3021C>T p.S1007= | Silent (SNP) | VAF 35/335 reads (10%) | called by muse, mutect2, varscan2
- CENPE | c.4551C>T p.I1517= | Silent (SNP) | VAF 28/206 reads (14%) | called by muse, mutect2, varscan2
- CEP250 | c.6171G>A p.R2057= | Silent (SNP) | VAF 48/458 reads (10%) | catalogued as COSV100698916; called by muse, mutect2
- CNGA3 | c.1671G>A p.G557= | Silent (SNP) | VAF 47/467 reads (10%) | called by muse, mutect2, varscan2
- COL4A2 | c.348C>T p.A116= | Silent (SNP) | VAF 26/315 reads (8%) | catalogued as rs1223427718, COSV100847372, COSV64626264; called by muse, mutect2
- COLEC11 | c.606C>T p.F202= | Silent (SNP) | VAF 72/582 reads (12%) | called by muse, mutect2, varscan2
- CROCC | c.1569G>A p.L523= | Silent (SNP) | VAF 82/854 reads (10%) | catalogued as rs763218957; called by muse, mutect2
- CSMD3 | c.7050C>T p.I2350= (on ENST00000297405 / NM_001363185.1; = p.I2246= on NM_052900.3) | Silent (SNP) | VAF 33/418 reads (8%) | catalogued as rs142588028, COSV99846430; called by muse, mutect2
- DCDC2C | c.495C>T p.I165= | Silent (SNP) | VAF 19/265 reads (7%) | catalogued as rs1417282082, COSV70977352; called by muse, mutect2
- EBI3 | c.567C>T p.I189= | Silent (SNP) | VAF 44/332 reads (13%) | called by muse, mutect2
- EHD3 | c.966C>T p.F322= | Silent (SNP) | VAF 38/341 reads (11%) | catalogued as rs772720205, COSV100434636, COSV59029287; called by muse, mutect2, varscan2
- ELFN2 | c.1002C>T p.S334= | Silent (SNP) | VAF 42/419 reads (10%) | catalogued as rs138546342; called by muse, mutect2, varscan2
- EP400 | c.603C>T p.I201= | Silent (SNP) | VAF 38/392 reads (10%) | catalogued as rs575382887; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHB6 | c.1950C>T p.S650= | Silent (SNP) | VAF 45/483 reads (9%) | catalogued as rs765773475, COSV100844402; called by muse, mutect2
- ERVV-1 | c.21C>T p.F7= | Silent (SNP) | VAF 20/336 reads (6%) | catalogued as rs1301890726; called by muse, mutect2
- FAM171A1 | c.1170G>A p.T390= | Silent (SNP) | VAF 63/485 reads (13%) | catalogued as rs771844084, COSV65313645; called by muse, mutect2, varscan2
- FARP2 | c.2595A>T p.P865= | Silent (SNP) | VAF 38/304 reads (13%) | called by muse, mutect2, varscan2
- FASN | c.2829C>T p.A943= | Silent (SNP) | VAF 32/290 reads (11%) | called by muse, mutect2, varscan2
- FCGR3B | c.156C>T p.S52= | Silent (SNP) | VAF 85/400 reads (21%) | catalogued as COSV99670366; called by muse, mutect2, varscan2
- FGA | c.702C>T p.P234= | Silent (SNP) | VAF 36/390 reads (9%) | catalogued as rs774638560, COSV57395360; called by muse, mutect2
- GIMAP8 | c.762G>A p.G254= | Silent (SNP) | VAF 55/456 reads (12%) | catalogued as COSV56231526; called by muse, mutect2, varscan2
- GLIS3 | c.1770G>A p.G590= | Silent (SNP) | VAF 43/339 reads (13%) | catalogued as rs758580169; called by muse, mutect2, varscan2
- GPX5 | c.579C>T p.I193= | Silent (SNP) | VAF 156/614 reads (25%) | called by muse, mutect2, varscan2
- GRIK3 | c.426G>C p.L142= | Silent (SNP) | VAF 78/555 reads (14%) | called by muse, mutect2, varscan2
- HBD | c.141G>A p.G47= | Silent (SNP) | VAF 43/323 reads (13%) | catalogued as COSV99496617; called by muse, mutect2, varscan2
- HOMER3 | c.1085G>A p.*362= | Silent (SNP) | VAF 53/419 reads (13%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.69A>G p.Q23= | Silent (SNP) | VAF 56/435 reads (13%) | called by muse, mutect2, varscan2
- HTR2C | c.669C>T p.F223= | Silent (SNP) | VAF 73/303 reads (24%) | called by muse, mutect2, varscan2
- IGLV3-10 | c.114G>A p.R38= | Silent (SNP) | VAF 50/435 reads (11%) | catalogued as rs768059672; called by muse, mutect2
- KCNG2 | c.399C>T p.A133= | Silent (SNP) | VAF 33/185 reads (18%) | called by muse, mutect2, varscan2
- KCNN4 | c.792G>A p.K264= | Silent (SNP) | VAF 42/333 reads (13%) | called by muse, mutect2, varscan2
- KIAA1671 | c.5286C>T p.F1762= | Silent (SNP) | VAF 66/730 reads (9%) | called by muse, mutect2
- KLHL4 | c.477C>T p.F159= | Silent (SNP) | VAF 50/217 reads (23%) | called by muse, mutect2, varscan2
- LRIF1 | c.1362C>A p.T454= | Silent (SNP) | VAF 32/286 reads (11%) | catalogued as COSV100870943; called by mutect2, varscan2
- LRP1B | c.4551G>A p.Q1517= | Silent (SNP) | VAF 30/320 reads (9%) | called by muse, mutect2
- MAP3K19 | c.3852G>A p.G1284= | Silent (SNP) | VAF 28/308 reads (9%) | called by muse, mutect2
- MAP3K19 | c.3102C>T p.D1034= | Silent (SNP) | VAF 28/279 reads (10%) | called by muse, mutect2
- MED15 | c.1770C>T p.I590= (on ENST00000263205 / NM_001003891.3; = p.I550= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/410 reads (11%) | catalogued as rs369151271; called by muse, mutect2, varscan2
- MEGF11 | c.252G>A p.R84= | Silent (SNP) | VAF 51/441 reads (12%) | catalogued as rs1313854483; called by muse, mutect2, varscan2
- MRPL32 | c.411C>T p.I137= | Silent (SNP) | VAF 48/448 reads (11%) | catalogued as COSV56239124; called by muse, mutect2, varscan2
- MUC16 | c.18390C>T p.S6130= | Silent (SNP) | VAF 40/491 reads (8%) | catalogued as rs1233429622, COSV101197562, COSV101199050; called by muse, mutect2
- MVP | c.2583G>A p.R861= | Silent (SNP) | VAF 64/421 reads (15%) | called by muse, mutect2, varscan2
- MYO3A | c.441C>T p.I147= | Silent (SNP) | VAF 23/171 reads (13%) | catalogued as rs769644196; called by muse, mutect2, varscan2
- MYT1L | c.1155G>A p.L385= | Silent (SNP) | VAF 60/614 reads (10%) | called by muse, mutect2
- N6AMT1 | c.507C>T p.F169= | Silent (SNP) | VAF 35/231 reads (15%) | called by muse, mutect2, varscan2
- NCKAP5 | c.2982G>A p.K994= | Silent (SNP) | VAF 24/352 reads (7%) | catalogued as rs1487157927, COSV58472233; called by muse, mutect2
- NLRP4 | c.1617G>A p.G539= | Silent (SNP) | VAF 55/368 reads (15%) | catalogued as COSV100017101; called by muse, mutect2, varscan2
- NPAP1 | c.2631A>G p.A877= | Silent (SNP) | VAF 40/377 reads (11%) | catalogued as rs1367338924; called by muse, mutect2, varscan2
- NPC1L1 | c.1212C>T p.F404= | Silent (SNP) | VAF 46/451 reads (10%) | called by muse, mutect2, varscan2
- NRK | c.345G>A p.K115= | Silent (SNP) | VAF 54/182 reads (30%) | called by muse, mutect2, varscan2
- NUDT13 | c.666G>A p.K222= | Silent (SNP) | VAF 38/245 reads (16%) | catalogued as rs773609984; called by muse, mutect2, varscan2
- OLIG1 | c.30G>C p.V10= | Silent (SNP) | VAF 82/610 reads (13%) | called by muse, mutect2, varscan2
- OR1F1 | c.339C>T p.F113= | Silent (SNP) | VAF 66/435 reads (15%) | catalogued as COSV58960406; called by muse, mutect2, varscan2
- OR1N1 | c.624C>T p.P208= | Silent (SNP) | VAF 38/370 reads (10%) | called by muse, mutect2
- OR2AP1 | c.201G>A p.L67= | Silent (SNP) | VAF 52/401 reads (13%) | catalogued as rs894168331; called by muse, mutect2, varscan2
- OR2T5 | c.351C>T p.F117= | Silent (SNP) | VAF 5/19 reads (26%) | called by mutect2, varscan2
- OR8H2 | c.189C>T p.F63= | Silent (SNP) | VAF 42/384 reads (11%) | catalogued as COSV57944806; called by muse, mutect2, varscan2
- PCLO | c.5097G>A p.L1699= | Silent (SNP) | VAF 46/510 reads (9%) | catalogued as rs367785097; called by muse, mutect2
- PLEC | c.645C>T p.S215= (on ENST00000322810 / NM_201380.4; = p.S105= on NM_000445.5) | Silent (SNP) | VAF 58/500 reads (12%) | catalogued as rs781788114; called by muse, mutect2, varscan2
- PPM1E | c.1140C>G p.A380= | Silent (SNP) | VAF 33/213 reads (15%) | called by muse, mutect2, varscan2
- PURB | c.441C>T p.R147= | Silent (SNP) | VAF 66/690 reads (10%) | called by muse, mutect2
- PXYLP1 | c.1359C>G p.V453= | Silent (SNP) | VAF 67/399 reads (17%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.1471C>T p.L491= | Silent (SNP) | VAF 58/666 reads (9%) | catalogued as rs1400994465; called by muse, mutect2
- RAB11FIP5 | c.1470C>T p.I490= | Silent (SNP) | VAF 56/664 reads (8%) | catalogued as rs749724196; called by muse, mutect2
- RAI1 | c.309G>A p.Q103= | Silent (SNP) | VAF 79/594 reads (13%) | called by muse, mutect2, varscan2
- RAMP3 | c.180C>T p.S60= | Silent (SNP) | VAF 54/349 reads (15%) | catalogued as rs1003173817; called by muse, mutect2, varscan2
- RGS14 | c.252C>T p.F84= | Silent (SNP) | VAF 37/261 reads (14%) | catalogued as rs1477360491; called by muse, mutect2, varscan2
- ROR2 | c.1479C>T p.F493= | Silent (SNP) | VAF 69/462 reads (15%) | catalogued as rs368196613, COSV65218463; called by muse, mutect2, varscan2
- RUFY4 | c.567G>A p.R189= | Silent (SNP) | VAF 30/428 reads (7%) | catalogued as COSV100722843, COSV60247690; called by muse, mutect2
- RYR1 | c.4521G>A p.R1507= | Silent (SNP) | VAF 46/403 reads (11%) | catalogued as COSV62105098; called by muse, mutect2, varscan2
- SALL3 | c.2610G>A p.G870= | Silent (SNP) | VAF 80/634 reads (13%) | catalogued as COSV73306639; called by muse, mutect2, varscan2
- SCRIB | c.2454G>A p.E818= | Silent (SNP) | VAF 72/855 reads (8%) | called by muse, mutect2
- SGSH | c.141C>T p.T47= | Silent (SNP) | VAF 58/441 reads (13%) | called by muse, mutect2, varscan2
- SH3GL2 | c.1023C>T p.I341= | Silent (SNP) | VAF 53/286 reads (19%) | called by muse, mutect2, varscan2
- SHPK | c.231C>T p.P77= | Silent (SNP) | VAF 57/412 reads (14%) | called by muse, mutect2, varscan2
- SKOR1 | c.1359C>T p.G453= | Silent (SNP) | VAF 95/774 reads (12%) | called by muse, mutect2, varscan2
- SLC7A4 | c.1824C>T p.F608= | Silent (SNP) | VAF 61/501 reads (12%) | catalogued as rs1276103836; called by muse, mutect2, varscan2
- SLCO1C1 | c.573C>T p.F191= | Silent (SNP) | VAF 49/464 reads (11%) | catalogued as COSV56871785, COSV56879186; called by muse, mutect2
- SLIT1 | c.1374C>T p.P458= | Silent (SNP) | VAF 55/399 reads (14%) | called by muse, mutect2, varscan2
- SPTBN1 | c.5412C>T p.S1804= | Silent (SNP) | VAF 32/408 reads (8%) | called by muse, mutect2
- SSC5D | c.4320C>T p.P1440= | Silent (SNP) | VAF 61/454 reads (13%) | called by muse, mutect2, varscan2
- TEDC1 | c.1227G>A p.K409= (on ENST00000392523 / NM_001367178.1; = p.K340= on NM_001134875.1) | Silent (SNP) | VAF 66/435 reads (15%) | called by muse, mutect2, varscan2
- THNSL2 | c.1197C>T p.Y399= | Silent (SNP) | VAF 42/481 reads (9%) | called by muse, mutect2
- TMEM168 | c.1614C>T p.S538= | Silent (SNP) | VAF 45/350 reads (13%) | catalogued as rs752103834; called by muse, mutect2, varscan2
- TMEM53 | c.198C>T p.I66= | Silent (SNP) | VAF 26/229 reads (11%) | called by muse, mutect2, varscan2
- TMPRSS13 | c.1725C>T p.S575= | Silent (SNP) | VAF 60/471 reads (13%) | called by muse, mutect2, varscan2
- TNR | c.3201G>A p.E1067= | Silent (SNP) | VAF 78/292 reads (27%) | catalogued as rs753307143; called by muse, mutect2, varscan2
- TSPYL5 | c.243C>T p.L81= | Silent (SNP) | VAF 102/978 reads (10%) | catalogued as rs909808475; called by muse, mutect2
- TTN | c.66957C>T p.I22319= (on ENST00000591111; = p.I14895= on NM_003319.4) | Silent (SNP) | VAF 52/415 reads (13%) | catalogued as COSV100599747, COSV59958093; called by muse, mutect2, varscan2
- ULK4 | c.3828G>A p.*1276= | Silent (SNP) | VAF 45/274 reads (16%) | called by muse, mutect2, varscan2
- UNC45B | c.1944G>A p.Q648= | Silent (SNP) | VAF 31/295 reads (11%) | called by muse, mutect2, varscan2
- VBP1 | c.48G>A p.G16= | Silent (SNP) | VAF 59/276 reads (21%) | catalogued as rs11544264; called by muse, mutect2, varscan2
- WDR11 | c.27G>A p.K9= | Silent (SNP) | VAF 58/434 reads (13%) | called by muse, mutect2, varscan2
- WIPI2 | c.1356G>A p.R452= | Silent (SNP) | VAF 38/465 reads (8%) | catalogued as rs756801702; called by muse, mutect2
- YIF1A | c.705C>T p.A235= | Silent (SNP) | VAF 51/555 reads (9%) | called by muse, mutect2
- ZFHX4 | c.9870C>T p.V3290= | Silent (SNP) | VAF 62/463 reads (13%) | catalogued as COSV51467324; called by muse, mutect2, varscan2
- ZGPAT | c.222G>A p.Q74= | Silent (SNP) | VAF 117/511 reads (23%) | catalogued as rs758958907; called by muse, mutect2, varscan2
- ZNF12 | c.1032G>A p.Q344= (on ENST00000405858 / NM_016265.4; = p.Q306= on NM_006956.3) | Silent (SNP) | VAF 45/434 reads (10%) | called by muse, mutect2, varscan2
- ZNF180 | c.1980C>T p.P660= | Silent (SNP) | VAF 39/330 reads (12%) | called by muse, mutect2, varscan2
- ZNF197 | c.69C>T p.T23= | Silent (SNP) | VAF 38/242 reads (16%) | called by muse, mutect2, varscan2
- ZNF274 | c.525C>T p.P175= (on ENST00000610905; = p.P70= on NM_016324.3) | Silent (SNP) | VAF 59/403 reads (15%) | catalogued as rs1390571769, COSV100465263, COSV58763928; called by muse, mutect2, varscan2
- ZNF442 | c.585C>T p.N195= | Silent (SNP) | VAF 34/249 reads (14%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148187 G>A | 5'Flank (SNP) | VAF 46/283 reads (16%) | called by muse, mutect2, varscan2
- ASIC1 | c.559-3019C>T | Intron (SNP) | VAF 56/394 reads (14%) | called by muse, mutect2, varscan2
- BAD | c.*143C>T | 3'UTR (SNP) | VAF 32/282 reads (11%) | catalogued as COSV99657319; called by muse, mutect2, varscan2
- C9orf129 | n.537G>A | RNA (SNP) | VAF 63/433 reads (15%) | called by muse, mutect2, varscan2
- FLT4 | c.*357C>T | 3'UTR (SNP) | VAF 49/309 reads (16%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+37435G>A | Intron (SNP) | VAF 82/668 reads (12%) | called by mutect2, varscan2
- LYPD6B | c.5+29846C>T | Intron (SNP) | VAF 34/356 reads (10%) | called by muse, mutect2
- NHS | c.853-2047G>A | Intron (SNP) | VAF 47/227 reads (21%) | catalogued as rs960230379; called by muse, mutect2, varscan2
- SLC45A4 | c.*104C>T | 3'UTR (SNP) | VAF 40/445 reads (9%) | called by muse, mutect2
- TASOR2 | c.-223dup | 5'UTR (INS) | VAF 28/205 reads (14%) | catalogued as rs1367581319; called by mutect2, pindel, varscan2
